Gene-level copy-number profile of tumor specimen HCM-SANG-1093-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-1093-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1093-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 635f1f1e-da7e-4e64-acda-9e50a6ce1ab5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1093-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/199b0c19-a90c-4da1-b020-a568f260c5c7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 634; copy number 2: 57,367; copy number 3: 386; copy number 4: 6; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:49,257,411–49,472,085, 2 genes (within-gene range 0–1): AGBL4-AS1, AGBL4-IT1.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:147,344,629–147,344,717, 1 gene, copy number 5: MIR548G.
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.

Autosomal genes at a single copy (total copy number 1): 474. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
